Somatic mutation profile of tumor specimen TCGA-DD-A4NQ-01A (aliquot TCGA-DD-A4NQ-01A-21D-A28X-10) from TCGA case TCGA-DD-A4NQ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 60.5 years (22,111 days).
Specimen TCGA-DD-A4NQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc14b8a3-cb76-4240-b531-57e04586c05c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A4NQ-10A (Blood Derived Normal), aliquot TCGA-DD-A4NQ-10A-01D-A28X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da09e1d1-cffa-4211-84ee-63b669a9295c

The open-access MAF lists 87 somatic variants for this specimen: 70 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 14, Frame Shift Del 3, Nonsense Mutation 3, Splice Site 2, Intron 2, In Frame Del 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1BG | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs542119157, COSV54049650; called by muse, mutect2, varscan2
- AFAP1 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.132); catalogued as COSV61793303; called by muse, mutect2, varscan2
- BAZ2B | c.3394A>T p.M1132L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.515); catalogued as COSV54274891; called by muse, mutect2, varscan2
- BLK | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376140772; called by muse, mutect2, varscan2
- BTBD11 | c.2388G>T p.R796S (on ENST00000280758 / NM_001018072.2; = p.R333S on NM_001017523.2) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV55017387; called by muse, mutect2, varscan2
- CD37 | c.432C>G p.D144E | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV60543492; called by muse, mutect2, varscan2
- CFAP20DC | c.1450C>T p.P484S (on ENST00000482387 / NM_001351530.2; = p.P359S on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV55916300; called by muse, mutect2, varscan2
- CHRNA4 | c.1849C>T p.L617F | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64718502; called by muse, mutect2, varscan2
- CISD1 | c.232A>T p.K78* | Nonsense Mutation (SNP) | VAF 25/164 reads (15%) | catalogued as COSV61703147; called by muse, mutect2, varscan2
- COL4A4 | c.3472G>T p.D1158Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV61629657, COSV61629917; called by muse, mutect2, varscan2
- COL4A6 | c.29T>A p.L10Q | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV57859591; called by muse, mutect2, varscan2
- DAAM1 | c.2482C>G p.Q828E | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.928); catalogued as COSV62834193; called by muse, mutect2, varscan2
- DHRS7 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.574); catalogued as COSV53665350; called by muse, mutect2
- DVL1 | c.419T>C p.M140T | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs147424815; called by muse, mutect2, varscan2
- EPHA1 | c.859A>T p.M287L | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV51968603; called by muse, mutect2, varscan2
- FAM227B | c.1442_1445del p.R481Nfs*33 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as rs762888521; called by mutect2, pindel, varscan2
- FBLN2 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.743); catalogued as COSV55480893; called by muse, mutect2, varscan2
- FCRLB | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV61059327; called by muse, mutect2
- GLI2 | c.33G>T p.E11D | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.169); catalogued as COSV58033813, COSV58034879; called by muse, mutect2, varscan2
- GRAMD1B | c.2007A>T p.E669D | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV59200611; called by muse, mutect2, varscan2
- GRHL1 | c.194A>G p.Y65C | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1198161783, COSV61406460; called by muse, mutect2, varscan2
- GUF1 | c.302A>G p.N101S | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV55781484; called by muse, varscan2
- HOXA3 | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57825166; called by mutect2, varscan2
- HOXD9 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV50890642; called by muse, mutect2, varscan2
- HUWE1 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.299); catalogued as COSV53335128; called by muse, mutect2, varscan2
- IPP | c.1557G>T p.M519I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV63431870; called by muse, mutect2, varscan2
- ITPRID1 | c.2518C>A p.Q840K | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV60070268; called by muse, mutect2, varscan2
- JAK3 | c.2477C>T p.S826L | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV71685588; called by muse, mutect2, varscan2
- KLHL2 | c.170A>T p.D57V | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56973753; called by muse, mutect2
- LAMA4 | c.5298G>C p.R1766S (on ENST00000230538 / NM_001105206.3; = p.R1759S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as COSV57892166; called by muse, mutect2, varscan2
- LTF | c.803G>T p.R268L | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as COSV51605648; called by muse, mutect2, varscan2
- MFAP2 | c.449-1G>C p.X150_splice | Splice Site (SNP) | VAF 14/70 reads (20%) | catalogued as COSV65003603; called by muse, mutect2, varscan2
- MPPED1 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV68837400; called by muse, mutect2, varscan2
- MROH1 | c.194T>G p.V65G | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV58187430; called by muse, mutect2, varscan2
- MYDGF | c.278C>A p.T93N | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV53560314; called by muse, mutect2, varscan2
- NAALADL1 | c.1184C>T p.T395I | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); catalogued as COSV60522935; called by muse, mutect2, varscan2
- NCLN | c.1384C>T p.Q462* | Nonsense Mutation (SNP) | VAF 25/101 reads (25%) | catalogued as COSV55741871; called by muse, mutect2, varscan2
- NLRC5 | c.1426T>A p.Y476N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV52649411; called by muse, mutect2, varscan2
- OR2A2 | c.366T>A p.Y122* | Nonsense Mutation (SNP) | VAF 19/146 reads (13%) | catalogued as COSV68871079; called by muse, mutect2, varscan2
- OR51D1 | c.28A>G p.I10V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1295960190, COSV62913884; called by muse, mutect2, varscan2
- OR51T1 | c.184T>A p.Y62N | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59023822; called by muse, mutect2, varscan2
- OR5H14 | c.583A>T p.N195Y | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71193473; called by muse, mutect2, varscan2
- PALB2 | c.1213C>A p.P405T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55162512; called by muse, mutect2, varscan2
- PCDHA3 | c.1682A>G p.N561S | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV63538994; called by muse, mutect2, varscan2
- PHACTR3 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63025235, COSV63025385; called by mutect2, varscan2
- PTPN22 | c.1174G>A p.D392N (on ENST00000359785 / NM_001193431.2; = p.D337N on NM_012411.5) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.073); catalogued as COSV63084350; called by muse, mutect2, varscan2
- PYGB | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs201813153, COSV53815817; called by muse, mutect2, varscan2
- RAB3IP | c.1220G>A p.R407K (on ENST00000550536 / NM_175623.4; = p.R391K on NM_022456.5) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as rs1156530661, COSV56081806, COSV99923541; called by muse, mutect2, varscan2
- RYR2 | c.5669A>C p.K1890T | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV63663294; called by muse, mutect2, varscan2
- SDK1 | c.6289T>C p.S2097P | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67357075; called by muse, mutect2, varscan2
- SEC23B | c.513G>C p.R171S | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV52718484, COSV52722471; called by muse, mutect2, varscan2
- SLC2A4 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0.358); catalogued as COSV50300386; called by muse, mutect2, varscan2
- SLC39A14 | c.1099A>G p.I367V | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as COSV51482337; called by muse, mutect2, varscan2
- SPATS2 | c.1417A>G p.M473V | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV58916761; called by muse, mutect2, varscan2
- SPEF2 | c.2422G>A p.A808T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV61544444; called by muse, mutect2, varscan2
- STK31 | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV63459788; called by muse, mutect2
- THAP7 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs756191065, COSV53145270; called by muse, mutect2, varscan2
- TNKS2 | c.199+1G>T p.X67_splice | Splice Site (SNP) | VAF 12/75 reads (16%) | catalogued as COSV65414703; called by muse, mutect2
- TRPC3 | c.529G>A p.D177N (on ENST00000379645 / NM_001366479.2; = p.D104N on NM_003305.2) | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV53372118; called by muse, mutect2, varscan2
- USP16 | c.1940G>T p.R647L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV57623956, COSV57624590; called by muse, mutect2, varscan2
- ZFAT | c.2126G>T p.R709L | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV64734564; called by muse, mutect2, varscan2
- ZFHX4 | c.8459A>C p.N2820T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV50501814; called by muse, mutect2, varscan2
- ZFPM2 | c.1359A>T p.R453S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as COSV101022931, COSV65872593; called by muse, mutect2
- AXIN1 | c.2043_2048delinsAC p.S682Rfs*22 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by pindel, varscan2*
- IGKV1D-43 | c.206T>C p.F69S | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SPATA31A1 | c.3811G>T p.A1271S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- TRIM67 | c.1985dup p.N662Kfs*24 | Frame Shift Ins (INS) | VAF 73/269 reads (27%) | called by mutect2, pindel, varscan2
- TSC2 | c.4777_4782del p.Y1593_L1594del | In Frame Del (DEL) | VAF 31/154 reads (20%) | called by mutect2, pindel, varscan2
- TUBE1 | c.51_62del p.C18_W21del | In Frame Del (DEL) | VAF 28/228 reads (12%) | called by pindel, varscan2
- WDR49 | c.745del p.I249Yfs*80 (on ENST00000308378 / NM_001366158.1; = p.I590Yfs*80 on NM_001348951.2 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- AMZ1 | c.39G>A p.G13= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs1349523284, COSV56684926; called by muse, mutect2, varscan2
- ASIC1 | c.1119C>T p.G373= | Silent (SNP) | VAF 49/292 reads (17%) | catalogued as rs1171844385, COSV57316175, COSV57319733; called by muse, mutect2, varscan2
- CAMTA1 | c.516C>T p.P172= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as rs775725704, COSV57882672; called by muse, mutect2, varscan2
- DGAT2 | c.978G>T p.G326= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV57175323; called by mutect2, varscan2
- DQX1 | c.2019A>T p.P673= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as COSV52045277; called by muse, mutect2, varscan2
- FGR | c.1080G>T p.V360= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as COSV64969229; called by muse, mutect2, varscan2
- FNTA | c.138C>T p.A46= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV56489200; called by muse, mutect2, varscan2
- FSIP2 | c.19266C>T p.V6422= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as rs751674952, COSV58078537; called by muse, mutect2, varscan2
- GLT8D2 | c.699C>G p.A233= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV100674162, COSV62561120; called by muse, mutect2, varscan2
- LMAN2L | c.6G>A p.A2= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV53840602; called by muse, mutect2, varscan2
- LYST | c.495C>A p.T165= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV67703457; called by muse, mutect2, varscan2
- OTUB1 | c.106C>A p.R36= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV56837877; called by mutect2, varscan2
- RSPH1 | c.846C>T p.D282= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV52318414; called by muse, mutect2, varscan2
- RYR1 | c.14583C>T p.R4861= | Silent (SNP) | VAF 41/243 reads (17%) | catalogued as COSV100615803, COSV62089299; called by muse, mutect2, varscan2
- PARP1 | c.-2G>T | 5'UTR (SNP) | VAF 36/156 reads (23%) | catalogued as COSV100828534; called by muse, mutect2, varscan2
- PDLIM3 | c.93+10249_93+10253del | Intron (DEL) | VAF 8/65 reads (12%) | called by mutect2, pindel, varscan2
- TP53 | c.993+220A>G | Intron (SNP) | VAF 14/40 reads (35%) | catalogued as COSV52734436; called by muse, mutect2, varscan2
